Surgical pathology report (de-identified scan), TCGA case TCGA-HS-A5N7, project TCGA-SARC (Sarcoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HS-A5N7-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	leiomyosarcoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	left retroperitoneal soft tissue mass
Tumour Size (cm)	9.2000000000000011
Histology	leiomyosarcoma
Grade/Differentiation	II
Pathological T	T2, NOS
Pathological N	N0
Clinical M	M0
Histology Comments	Grade: FNCLCC Grade 2 out of 3 (40-50% necrosis; 5-7 MF/10 HPF)

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

UUID:SDE34553-6601-48FF-A984-AB5BA191BAFA

ICD-O-3

Leiomyosarcoma NOS 8890/3
Site: Retroperitoneum C48.0
QW211113

Criteria	hw 2/7/13	Yes	No

Source: NCI Genomic Data Commons file 50286226-d6e9-49fe-97ef-dd9c3fa606a0 (TCGA-HS-A5N7.5DE34553-6601-48FF-A984-AB5BA191BAFA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).